HCMI case HCM-EXPT-0882-C25 — NCI Cancer Model Development for the Human Cancer Model Initiative (HCMI-CMDC)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Ductal and Lobular Neoplasms; Primary site: Pancreas.
https://portal.gdc.cancer.gov/cases/a394e01a-d47f-4eb5-aa2d-89e684936271

Demographics
Sex at birth: female; Year of birth: 1950.

Diagnoses (1)
1. Infiltrating duct carcinoma, NOS: ICD-O-3 morphology code: 8500/3; ICD-10 code: C25.2; Tissue or organ of origin: Pancreas, NOS; Site of resection or biopsy: Tail of pancreas; Classification of tumor: primary; Age at diagnosis: 68.0 years (24,839 days); Prior treatment: No.
   Recorded as not given: neoadjuvant treatment (type not reported).

Biospecimens (1 sample; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample HCM-EXPT-0882-C25-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: Frozen.
  Slide HCM-EXPT-0882-C25-01A-01-S2-HE: Section location: Bottom; Percent tumor cells: 98; Percent tumor nuclei: 50; Percent normal cells: 0; Percent necrosis: 2; Percent stromal cells: 0; Percent lymphocyte infiltration: 0; Percent monocyte infiltration: 0; Percent neutrophil infiltration: 0.
  Slide HCM-EXPT-0882-C25-01A-01-S1-HE: Section location: Top; Percent tumor cells: 90; Percent tumor nuclei: 50; Percent normal cells: 10; Percent necrosis: 0; Percent stromal cells: 0; Percent lymphocyte infiltration: 0; Percent monocyte infiltration: 0; Percent neutrophil infiltration: 0.
